Somatic mutation profile of tumor specimen BA2649D (aliquot aq-BA2649D) from BEATAML1.0 case 2097, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.9 years (24,061 days).
Specimen BA2649D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12da7ed5-2203-4331-a42f-fe369b4074b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2378D (Solid Tissue Normal), aliquot aq-BA2378D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/471e230e-7023-4b03-b0aa-5eb9bc1191c1

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Splice Region 2, Intron 2, Frame Shift Del 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by mutect2, varscan2
- SF3B1 | c.1998G>T p.K666N | Missense Mutation (SNP) | VAF 87/225 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.6344G>C p.R2115P | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51657239; called by muse, mutect2, varscan2
- CNTN5 | c.2166C>A p.V722= | Splice Region (SNP) | VAF 3/38 reads (8%) | catalogued as COSV54341340; called by muse, mutect2
- DLEC1 | c.3731C>T p.S1244F | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100341595; called by muse, mutect2, varscan2
- GRIA1 | c.1134G>A p.K378= | Splice Region (SNP) | VAF 43/88 reads (49%) | catalogued as rs1299953702, COSV99600502; called by muse, varscan2
- HUNK | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.132); catalogued as rs367545209, COSV54224467, COSV54229031; called by muse, mutect2, varscan2
- PDYN | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370283678, COSV54101461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLA2G5 | c.361A>G p.N121D | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs781232156; called by muse, mutect2, varscan2
- ATP10D | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CRLF1 | c.1112del p.L371Rfs*55 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel*, varscan2
- IARS1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IFT172 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.221); called by muse, mutect2
- MRPS10 | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRPM2 | c.2339del p.D780Vfs*22 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- PXDNL | c.2538C>T p.N846= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs761089744; called by muse, mutect2, varscan2
- COL4A2 | c.1340-168G>A | Intron (SNP) | VAF 86/190 reads (45%) | catalogued as rs760849887; called by muse, varscan2
- MAGED1 | c.45+224C>T | Intron (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
